Gene-level copy-number profile of tumor specimen C3N-02713-03 from CPTAC case C3N-02713, project CPTAC-3 (Larynx — Squamous Cell Neoplasms). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Larynx, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: G3; Age at diagnosis: 64.9 years (23,707 days).
Specimen C3N-02713-03: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Larynx; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 570fcced-0968-4eb1-96d8-75de9f7ecd19.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator C3N-02713-71 (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,729 have no estimate.
https://portal.gdc.cancer.gov/files/c61cbcd7-1c8c-4029-8604-23e5d1e51ca5

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 409; copy number 1: 2,006; copy number 2: 16,646; copy number 3: 16,418; copy number 4: 15,803; copy number 5: 4,856; copy number 6: 2,201; copy number 7: 273; copy number 8: 128; copy number 9: 41; copy number 11: 6; copy number 15: 1; copy number 18: 17; copy number 42: 30; copy number 49: 18; copy number 50: 9; copy number 54: 32.

Homozygous deletions (total copy number 0; autosomes only): 68 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:64,091–1,708,476, 28 genes (within-gene range 0–3): AC144568.1, AC144568.2, AC131281.2, WBP1LP3, OR4F21, SEPTIN14P8, AC131281.1, RPL23AP53, ZNF596, AC004908.2, AC004908.1, AC004908.3, AC136777.2, AC136777.1, FAM87A, FBXO25, AC083964.1, AC083964.2, TDRP, ERICH1, AC100797.1, DLGAP2, AC100797.4, AC026950.2, AC129915.3, AC110288.1, AF067845.2, AF067845.1.
- chr9:21,206,181–22,029,594, 36 genes (within-gene range 0–2): IFNA10, IFNWP18, IFNA16, IFNA17, IFNWP5, IFNA14, IFNA22P, IFNA5, IFNA20P, KLHL9, IFNA6, IFNA13, IFNA2, AL353732.1, IFNA11P, IFNA12P, IFNA8, AL353732.2, IFNWP2, IFNA1, MIR31HG, IFNWP19, IFNE, MIR31, SNORD39, H3P30, KHSRPP1, RN7SL151P, MTAP, AL359922.1, TUBB8P1, AL359922.2, AL359922.3, ERVFRD-3, CDKN2A-DT, CDKN2A.
- chr9:21,995,482–21,996,013, 1 gene (within-gene range 0–2): AL449423.1.
- chr9:61,642,383–61,642,494, 1 gene: Y_RNA.
- chr19:18,631,646–18,631,908, 1 gene: RN7SL155P.
- chr22:15,635,180–15,644,330, 1 gene: MED15P7.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 7,611 genes in 41 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:118,614,333–120,977,585, 59 genes, copy number 6: PSMC1P12, AL139148.1, TBX15, AL139420.1, AL139420.2, WARS2, WARS2-IT1, RBMX2P3, RPS3AP12, WARS2-AS1, RPL6P2, AL359915.1, LINC01780, RNU1-75P, HAO2, HAO2-IT1, HSD3B2, GAPDHP74, HSD3BP2, GAPDHP23, HSD3BP1, GAPDHP58, HSD3B1, GAPDHP32, HSD3BP3, GAPDHP27, HSD3BP4, GAPDHP33, LINC00622, HSD3BP5, ZNF697, PHGDH, HMGCS2, REG4, NBPF7, PFN1P9, NOTCH2P1, ADAM30, NOTCH2, AC245008.1, RNU6-465P, SEC22B, AC244669.2, 7SK, AC244669.1, U1, NBPF8, PFN1P2, AC241952.1, U2, 7SK, NOTCH2NLR, NBPF26, AC253572.1, RNVU1-19, PPIAL4A, AC241377.3, RNVU1-4, AC241377.4.
- chr1:224,896,262–248,937,043, 569 genes, copy number 5–15 (broad region; genes not listed).
- chr2:65,436,711–66,200,373, 2 genes, copy number 5 (within-gene range 4–7): AC007389.1, AC012370.2.
- chr2:65,589,566–72,148,038, 125 genes, copy number 5–7 (broad region; genes not listed).
- chr2:87,439,523–91,580,863, 123 genes, copy number 5–7 (broad region; genes not listed).
- chr2:203,315,390–204,379,792, 17 genes, copy number 18: MRPL50P2, ABI2, AC080075.1, RAPH1, AC125238.2, AC125238.1, CD28, KRT18P39, NPM1P33, RNU6-474P, CTLA4, ICOS, AC009965.2, AC009965.1, AC009498.1, DSTNP5, AC106901.1.
- chr3:75,521,803–75,522,012, 1 gene, copy number 5: SNRPCP10.
- chr3:95,654,423–98,208,341, 30 genes, copy number 5: MTHFD2P1, AC107304.1, HNRNPKP4, MIR8060, AC107015.1, RNU6-1094P, MTRNR2L12, RPL18AP8, RCC2P5, CDV3P1, EPHA6, AC117470.1, AC110491.1, ARL6, AC110491.3, CRYBG3, AC110491.2, RIOX2, GABRR3, OR5BM1P, OR5AC1, OR5AC2, AC117460.1, OR5AC4P, POU5F1P7, OR5H1, OR5H14, OR5H15, OR5H5P, OR5H3P.
- chr3:125,388,934–148,226,606, 420 genes, copy number 5–7 (within-gene range 4–7) (broad region; genes not listed).
- chr3:168,858,659–171,460,408, 57 genes, copy number 42–50 (within-gene range 2–50): RPL21P43, LINC02082, AC092954.1, AC092954.2, LINC01997, MECOM, MECOM-AS1, RPL22P1, AC007849.1, SDHDP3, RNU6-637P, TERC, Telomerase-vert, ACTRT3, AC078802.1, MYNN, AC078795.1, LRRC34, AC078795.3, AC078795.2, LRRIQ4, LRRC31, KRT18P43, SAMD7, AC008040.2, AC008040.1, AC008040.3, SEC62, SEC62-AS1, GPR160, RNU4-38P, KMT5AP3, PHC3, RNU6-315P, PRKCI, Y_RNA, AC073288.1, SKIL, AC073288.2, CLDN11, AC026316.4, MIR6828, SLC7A14-AS1, SLC7A14, KRT8P13, AC026316.1, AC026316.3, AC026316.5, AC026316.2, RPL22L1, EIF5A2, AC061708.1, KLF7P1, RNU1-70P, SLC2A2, TNIK, MIR569.
- chr3:181,699,608–181,699,883, 1 gene, copy number 54 (within-gene range 4–54): AC117415.1.
- chr3:181,847,526–192,917,856, 209 genes, copy number 5–54 (broad region; genes not listed).
- chr4:114,598,770–115,113,876, 5 genes, copy number 5: UGT8, MIR577, CIR1P2, RN7SL808P, NDST4.
- chr4:151,277,171–151,291,453, 2 genes, copy number 5 (within-gene range 4–5): PRSS48, AC104819.2.
- chr4:151,333,775–190,092,279, 526 genes, copy number 5 (broad region; genes not listed).
- chr5:58,198–45,895,970, 679 genes, copy number 5 (broad region; genes not listed).
- chr6:68,040,290–68,093,001, 2 genes, copy number 7: AL646090.2, AL646090.1.
- chr7:88,749,470–109,764,357, 454 genes, copy number 5–6 (broad region; genes not listed).
- chr8:36,378,069–37,095,390, 9 genes, copy number 5–11: AC090809.1, RPL23P10, RNA5SP264, KCNU1, AC124076.1, TPT1P8, AC090453.1, AC092818.1, SMARCE1P4.
- chr8:127,578,473–128,220,803, 15 genes, copy number 8: AC104370.1, CASC11, MYC, PVT1, MIR1204, AC084123.1, TMEM75, MIR1205, RNVU1-32, MIR1206, AC103705.1, RNU4-25P, MIR1207, MIR1208, RN7SKP226.
- chr8:128,634,199–130,655,712, 24 genes, copy number 8 (within-gene range 4–8): CCDC26, AC103833.2, AC103833.1, RN7SKP206, AC011257.1, MIR3686, MTRF1LP2, GSDMC, AC022973.5, CYRIB, AC022973.2, AC022973.1, AC022973.4, AC022973.3, AC131568.1, RNU7-181P, MIR5194, ASAP1, RNU6-1255P, ASAP1-IT2, AC103725.1, AC009682.1, AC139019.1, AC090987.1.
- chr8:131,712,512–133,302,022, 20 genes, copy number 6–8: AC060788.1, EFR3A, OC90, AC100868.1, HHLA1, KCNQ3, HPYR1, LRRC6, TMEM71, AF228727.1, PHF20L1, AF230666.2, AF230666.1, TG, AF305872.1, SLA, MIR7848, PTCSC1, CCN4, NDRG1.
- chr8:133,886,496–145,066,685, 243 genes, copy number 5–8 (broad region; genes not listed).
- chr10:32,446,140–35,800,920, 49 genes, copy number 6: CCDC7, C1DP1, ITGB1, AK3P5, ITGB1-DT, MTND4LP11, RN7SL847P, AL365203.1, RPL7AP53, IATPR, NRP1, AL121748.1, RN7SL398P, AL353600.1, LINC02628, AL450313.1, LINC00838, RPL23P11, LINC02629, PARD3, Y_RNA, ELOBP4, RPL37P18, RPS12P16, PARD3-AS1, SS18L2P1, RNU6-847P, RNU6-193P, PRDX2P2, CUL2, MIR3611, AL392046.1, CREM, RNU7-77P, ATP6V1G1P4, AL117336.1, LINC02634, RNU6-794P, CCNY, RNU6-1167P, AL117336.2, AL603824.1, AL121749.1, GJD4, FZD8, AL121749.2, MIR4683, RPL7P37, PCAT5.
- chr10:42,149,310–43,981,102, 63 genes, copy number 7 (broad region; genes not listed).
- chr12:12,310–39,619,803, 859 genes, copy number 5 (broad region; genes not listed).
- chr14:31,489,956–41,604,988, 151 genes, copy number 5–6 (broad region; genes not listed).
- chr14:57,200,507–106,879,812, 1,294 genes, copy number 6 (broad region; genes not listed).
- chr16:46,469,341–66,696,743, 407 genes, copy number 5 (broad region; genes not listed).
- chr17:18,415,728–18,506,313, 10 genes, copy number 6: KRT17P5, YWHAEP2, KRT17P2, KRT16P1, KRT16P4, AL353997.1, AL353997.4, TNPO1P2, LGALS9C, NOS2P2.
- chr17:54,702,936–83,240,804, 895 genes, copy number 5 (broad region; genes not listed).
- chr19:11,420,604–11,559,236, 12 genes, copy number 6: CCDC151, PRKCSH, ELAVL3, AC008481.3, ZNF653, MIR7974, ECSIT, RN7SL833P, AC008481.2, AC008481.1, CNN1, ELOF1.
- chr19:11,767,000–12,874,952, 90 genes, copy number 5–9 (within-gene range 3–9) (broad region; genes not listed).
- chr19:14,514,769–14,565,980, 2 genes, copy number 5 (within-gene range 3–5): DNAJB1, TECR.
- chr19:14,566,078–14,897,845, 18 genes, copy number 5: NDUFB7, CLEC17A, RN7SL337P, RN7SL842P, ADGRE3, ITGB1P1, AC022149.1, ZNF333, ADGRE2, OR7C1, AC005255.1, OR7A5, OR7A10, OR7A8P, OR7A2P, OR7A17, OR7A18P, OR7A1P.
- chr19:14,916,428–15,871,852, 51 genes, copy number 8: OR7A11P, OR7A15P, OR7C2, SLC1A6, CCDC105, CASP14, OR1I1, SYDE1, ILVBL, AC003956.1, OR10B1P, RNU6-782P, NOTCH3, MIR6795, AC004257.1, EPHX3, BRD4, AC005776.1, AC005776.2, AKAP8, AC005785.1, AKAP8L, AC005785.2, AC006128.1, WIZ, MIR1470, RASAL3, PGLYRP2, CYP4F22, AC011492.1, CYP4F23P, AD000091.1, RPL23AP2, AC093072.1, CYP4F8, CYP4F3, CYP4F10P, CYP4F12, OR10H2, OR10H3, CYP4F24P, AC004597.1, OR10H5, OR10H1, ZNF861P, AC004510.2, LINC01764, UCA1, AC004510.1, CLEC4O, CYP4F36P.
- chr20:31,514,410–31,577,923, 1 gene, copy number 5 (within-gene range 3–5): HM13.
- chr20:31,547,412–31,581,214, 5 genes, copy number 5: MCTS2P, HM13-IT1, HM13-AS1, AL110115.2, RNU6-384P.
- chr20:60,087,826–62,065,810, 19 genes, copy number 5: MIR646HG, MIR646, MTCO2P1, MIR4533, MIR548AG2, AL117372.1, AL139348.1, AL121910.1, LINC01718, CDH4, AL365229.1, BX640515.1, AL160412.1, AL162457.1, AL162457.2, TAF4, MIR1257, AL137077.1, MIR3195.
- chr20:62,804,835–64,327,972, 92 genes, copy number 5 (within-gene range 2–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 543. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
